Somatic mutation profile of tumor specimen TCGA-W2-A7HE-01A (aliquot TCGA-W2-A7HE-01A-11D-A35I-08) from TCGA case TCGA-W2-A7HE, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 80.1 years (29,241 days).
Specimen TCGA-W2-A7HE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1d4bbb3-d63a-4813-ad4a-f68d995caef9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W2-A7HE-10C (Blood Derived Normal), aliquot TCGA-W2-A7HE-10C-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/092eeec1-f46d-4905-9b62-68dabbbe6bff

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HCFC1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV60070202; called by muse, mutect2
- RNF213 | c.11099A>T p.N3700I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PCDHA10 | c.1179G>A p.P393= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs148283153, COSV100246875, COSV56486673; called by muse, mutect2, varscan2
